Somatic mutation profile of tumor specimen TCGA-E7-A541-01A (aliquot TCGA-E7-A541-01A-11D-A26M-08) from TCGA case TCGA-E7-A541, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.3 years (24,206 days).
Specimen TCGA-E7-A541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a7a5ad1-3624-418c-857f-5a7239288ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A541-10A (Blood Derived Normal), aliquot TCGA-E7-A541-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0540045b-0d3c-4b0a-aded-d44207291610

The open-access MAF lists 460 somatic variants for this specimen: 350 protein-altering or splice-affecting, 106 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 306, Silent 106, Nonsense Mutation 27, Splice Site 8, Frame Shift Del 6, Intron 2, Splice Region 2, Translation Start Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57250290, COSV57259763, COSV57263441; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3553G>T p.D1185Y (on ENST00000614293; = p.D1155Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55800238; called by muse, mutect2, varscan2
- ABCA8 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.434); catalogued as COSV52196127; called by muse, mutect2
- ABCC10 | c.3269G>A p.R1090Q (on ENST00000372530 / NM_001198934.2; = p.R1062Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369686699; called by muse, mutect2, varscan2
- ABHD14B | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV59985709; called by muse, mutect2
- ABL1 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs755821709, COSV59329904; called by muse, mutect2
- ABL2 | c.3208A>G p.R1070G (on ENST00000502732 / NM_007314.4; = p.R1055G on NM_005158.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61013041; called by muse, mutect2, varscan2
- AC104389.6 | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.191); catalogued as COSV100400634, COSV57963795; called by mutect2, varscan2
- ACAD10 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV58155841; called by muse, mutect2, varscan2
- ACTR2 | c.128C>A p.S43* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99573904; called by muse, mutect2
- ACTR2 | c.575A>C p.Y192S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV99573905; called by muse, mutect2
- ADCY5 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs148824947; called by muse, mutect2, varscan2
- AGL | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54051754; called by muse, mutect2, varscan2
- AHNAK2 | c.12805G>A p.E4269K | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs755133395, COSV60913165; called by muse, mutect2, varscan2
- AKAP12 | c.4018C>G p.Q1340E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53573658; called by muse, mutect2
- AL136295.1 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV99841733; called by muse, mutect2
- ALMS1 | c.12247G>T p.D4083Y | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as COSV52508193; called by muse, mutect2
- ANK1 | c.3063G>T p.R1021S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55879594; called by muse, mutect2, varscan2
- ANK2 | c.3133C>T p.H1045Y | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1303420613, COSV52157230; called by muse, mutect2
- ANKAR | c.3659A>T p.D1220V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV99854252; called by muse, mutect2
- ANKS1A | c.1751T>A p.L584* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | catalogued as COSV100832431; called by muse, mutect2
- AQP4 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV67218508; called by muse, mutect2
- ARAP3 | c.316_317del p.S106Wfs*38 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | catalogued as COSV53350166; called by mutect2, pindel, varscan2
- ARHGAP35 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.174); catalogued as COSV68330619; called by muse, mutect2, varscan2
- ARID1B | c.5472G>C p.K1824N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV51658760; called by muse, mutect2, varscan2
- ARMC3 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV53060138, COSV53062115; called by muse, mutect2, varscan2
- ARR3 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52103786; called by muse, mutect2
- ASTN1 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV56066915; called by muse, mutect2
- ATAD5 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV58973821; called by muse, mutect2, varscan2
- ATF7IP2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV61093199; called by muse, mutect2
- ATG2B | c.4712C>T p.T1571I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55890106; called by muse, mutect2
- ATP13A2 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV58699928; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57748785, COSV57750395; called by muse, mutect2, varscan2
- ATP6V1C2 | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV55359656; called by muse, mutect2, varscan2
- ATR | c.4582C>T p.L1528F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63385391, COSV63385889, COSV63388234; called by muse, mutect2, varscan2
- ATXN7L3 | c.608G>C p.S203T (on ENST00000389384 / NM_001382309.1; = p.S210T on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV60228659; called by muse, mutect2
- AXIN2 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61057144; called by muse, mutect2
- AZI2 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99843610; called by muse, mutect2, varscan2
- BAZ1B | c.1137C>G p.H379Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as rs1354375455, COSV59990570; called by muse, mutect2, varscan2
- BBS12 | c.285G>C p.W95C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58561901; called by muse, mutect2
- BCL2L13 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.292); catalogued as COSV58225550; called by muse, mutect2
- BRCA2 | c.1827A>C p.Q609H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66452521; called by muse, mutect2, varscan2
- BRINP3 | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750809290, COSV66521343, COSV66523532; called by mutect2, varscan2
- BROX | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61799213; called by muse, mutect2, varscan2
- BRS3 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65710903; called by muse, mutect2, varscan2
- BRWD3 | c.5200G>C p.D1734H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV64747032, COSV64750118; called by muse, mutect2, varscan2
- BSN | c.4202C>A p.A1401D | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV56516502, COSV56525115; called by muse, mutect2
- C10orf120 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61491839, COSV61492203; called by muse, mutect2
- C4orf19 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV52649193; called by muse, mutect2
- C9orf131 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV56610690; called by muse, mutect2, varscan2
- CACNA1S | c.5611C>G p.P1871A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100755522, COSV62938813; called by muse, mutect2
- CCDC81 | c.1526T>C p.I509T (on ENST00000445632 / NM_001156474.2; = p.I419T on NM_021827.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53577955; called by muse, mutect2, varscan2
- CCN1 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1205757605, COSV71704323; called by muse, mutect2
- CDCA3 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57528469; called by muse, mutect2, varscan2
- CDH15 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750047641, COSV57024135; called by muse, mutect2
- CDK3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs764867113, COSV56909958; called by muse, mutect2, varscan2
- CDKL2 | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV56733247; called by muse, mutect2
- CEACAM5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55751872; called by muse, mutect2, varscan2
- CEP76 | c.1274G>C p.S425T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50866186; called by muse, mutect2
- CFAP44 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55610724; called by muse, mutect2
- CGB3 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV62164376; called by muse, varscan2
- CHD4 | c.5390C>G p.S1797* (on ENST00000357008 / NM_001363606.2; = p.S1808* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100444938; called by muse, mutect2
- CHRND | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1278526717, COSV51318335; called by muse, mutect2, varscan2
- CHST15 | c.1230A>T p.K410N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60561596; called by mutect2, varscan2
- CLEC9A | c.471G>T p.M157I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV63350038; called by muse, mutect2
- COL14A1 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV52852562; called by muse, mutect2
- COL21A1 | c.171A>T p.K57N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55160093; called by muse, mutect2, varscan2
- COPG1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.166); catalogued as COSV59113704; called by muse, mutect2, varscan2
- COPS3 | c.1188G>C p.E396D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV52005053; called by muse, mutect2
- CPEB3 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99799475; called by muse, mutect2, varscan2
- CPT1C | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV54918800, COSV99773133; called by muse, mutect2, varscan2
- CR1 | c.3328G>C p.E1110Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV65457701; called by muse, mutect2
- CSMD3 | c.2000C>T p.P667L (on ENST00000297405 / NM_001363185.1; = p.P563L on NM_052900.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52159144; called by muse, mutect2, varscan2
- CSTF3 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV60610918; called by muse, mutect2, varscan2
- CTSW | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1419977241; called by muse, mutect2
- CYP4A22 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | catalogued as COSV99594881; called by muse, mutect2
- DAZAP2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV66312969; called by muse, mutect2, varscan2
- DCLRE1B | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV65812610; called by muse, mutect2
- DDX5 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56748864; called by muse, mutect2
- DENND3 | c.3187C>T p.Q1063* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99370964; called by mutect2, varscan2
- DGCR8 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.906); catalogued as COSV61226413; called by muse, mutect2
- DNAH12 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100244523; called by muse, mutect2
- DNAH17 | c.8914T>G p.F2972V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67752729; called by muse, mutect2, varscan2
- DNAH3 | c.6764A>C p.Y2255S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54516968; called by muse, mutect2, varscan2
- DNAH5 | c.11989C>G p.L3997V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54219454; called by muse, mutect2
- DNAH6 | c.1682A>G p.D561G | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV52857710; called by muse, mutect2
- DNAH7 | c.8183C>T p.S2728L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56760964; called by muse, mutect2, varscan2
- DNAH8 | c.9335G>A p.S3112N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV59440331; called by muse, mutect2
- DNAH9 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52345939; called by muse, mutect2
- DNM2 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV58960358; called by muse, mutect2
- DNMT3B | c.1529C>G p.T510R | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52417531; called by muse, mutect2
- DOCK9 | c.3445G>A p.D1149N (on ENST00000376460 / NM_001366676.2; = p.D1150N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59626244; called by muse, mutect2, varscan2
- DOCK9 | c.1876C>T p.P626S (on ENST00000376460 / NM_001366676.2; = p.P627S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.5); catalogued as COSV59626288; called by mutect2, varscan2
- DRD2 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.38); catalogued as rs776124526, COSV60757105; called by mutect2, varscan2
- DYTN | c.1082T>A p.L361H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV71751902; called by muse, mutect2
- EHBP1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV50418970; called by muse, mutect2
- ELK4 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56984592; called by muse, mutect2
- ENPP2 | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99308295; called by muse, mutect2
- EPPK1 | c.3773C>A p.A1258D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV101599840; called by muse, mutect2
- ESPL1 | c.5807C>T p.S1936L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as rs763549148, COSV54475697; called by muse, mutect2, varscan2
- FAM83H | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.653); catalogued as rs897332832, COSV66353734; called by muse, mutect2, varscan2
- FAM83H | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV101186979; called by muse, mutect2, varscan2
- FAM90A1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100274311; called by muse, mutect2
- FASTKD3 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52942976; called by muse, mutect2, varscan2
- FBLN1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as rs774139312, COSV53046389; called by muse, mutect2, varscan2
- FBN2 | c.5572G>C p.D1858H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV99327483; called by muse, mutect2
- FCN2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV99391277; called by muse, mutect2
- FGF23 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.338); catalogued as COSV52975772; called by muse, mutect2
- FRAS1 | c.10982C>T p.S3661L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53605224; called by muse, mutect2
- FRMD7 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.173); catalogued as COSV53745722, COSV53748439; called by muse, mutect2
- GAB3 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100850592; called by muse, mutect2, varscan2
- GAPDHS | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as rs770294359, COSV55882457; called by muse, mutect2, varscan2
- GAS7 | c.35T>G p.F12C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV71562133; called by muse, mutect2, varscan2
- GATA3 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV60517615; called by muse, mutect2, varscan2
- GBP3 | c.1183A>C p.K395Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as COSV52518159; called by muse, mutect2
- GDAP2 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.864); catalogued as COSV101032002; called by muse, mutect2
- GJA9 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62532029; called by muse, mutect2
- GML | c.296T>A p.F99Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV55277194; called by mutect2, varscan2
- GPALPP1 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV62705671; called by muse, mutect2
- GPD1 | c.613-1G>A p.X205_splice | Splice Site (SNP) | VAF 21/192 reads (11%) | catalogued as COSV56547863; called by muse, mutect2, varscan2
- GRIA3 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52056692; called by muse, mutect2, varscan2
- GRM5 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs1343286008, COSV100551952; called by muse, mutect2
- HAO1 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66491757, COSV66493596; called by mutect2, varscan2
- HARS1 | c.955T>G p.S319A | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.217); catalogued as COSV56906459; called by muse, mutect2
- HECW2 | c.4046T>G p.L1349R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53657014; called by muse, mutect2, varscan2
- HGF | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55956720; called by muse, mutect2
- HK2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51874750; called by muse, mutect2, varscan2
- HM13 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100159524, COSV59436133; called by muse, mutect2, varscan2
- HSPD1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV61443427, COSV61446053; called by muse, mutect2
- ICA1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1464009418, COSV99655326; called by muse, mutect2, varscan2
- ICAM1 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV53424617; called by muse, mutect2, varscan2
- ICE2 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV55030888; called by muse, mutect2, varscan2
- IGSF10 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56784312; called by muse, mutect2
- IL12B | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.137); catalogued as COSV51454690; called by muse, mutect2, varscan2
- IL1F10 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV61750261; called by muse, mutect2, varscan2
- IPO4 | c.1821G>C p.Q607H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV100269040; called by muse, mutect2
- IRX2 | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV57410788; called by muse, mutect2, varscan2
- ITGA7 | c.2731del p.H911Mfs*125 (on ENST00000555728; = p.H867Mfs*125 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as COSV57694299; called by mutect2, pindel, varscan2
- ITGAL | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.622); catalogued as COSV100776254; called by muse, mutect2
- ITGB5 | c.1378A>G p.N460D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.122); catalogued as COSV99950692; called by muse, mutect2
- JMJD1C | c.5321C>G p.S1774C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59514217; called by muse, mutect2, varscan2
- KARS1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100094067; called by muse, mutect2
- KCNB2 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV73049838; called by muse, mutect2, varscan2
- KCTD4 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368124187; called by muse, mutect2, varscan2
- KIDINS220 | c.4573G>T p.E1525* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99875717; called by muse, mutect2
- KLHL26 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs1301794630, COSV56317045; called by muse, mutect2
- KPNA2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs369989302; called by muse, mutect2, varscan2
- KRT7 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs754875031, COSV59329868; called by muse, mutect2, varscan2
- KTI12 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV65405732; called by muse, mutect2, varscan2
- LAMA3 | c.1679G>C p.G560A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV58067206; called by muse, mutect2, varscan2
- LAMA4 | c.1230A>T p.E410D (on ENST00000230538 / NM_001105206.3; = p.E403D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV57895607; called by muse, mutect2, varscan2
- LDB2 | c.891+1G>C p.X297_splice | Splice Site (SNP) | VAF 6/82 reads (7%) | catalogued as rs1371152908, COSV58767510; called by muse, mutect2
- LDOC1 | c.203T>G p.I68S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100983123; called by muse, mutect2
- LGALSL | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV53230388; called by muse, mutect2
- LGR5 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as rs1434992934, COSV57004376; called by muse, mutect2, varscan2
- LLGL1 | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100375381, COSV57499651; called by muse, mutect2
- LRIT3 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.944); catalogued as rs1486957859, COSV59984759; called by muse, mutect2, varscan2
- LRRC37B | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.423); catalogued as rs768851149, COSV58951942; called by muse, mutect2
- LRRC41 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs774215174, COSV58439713; called by muse, mutect2, varscan2
- MCTS1 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.912); catalogued as COSV100989164; called by muse, mutect2
- MGAM | c.3721T>C p.Y1241H | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074492; called by muse, mutect2
- MGAT5 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV56095865; called by muse, mutect2, varscan2
- MIB1 | c.1236T>A p.G412= | Splice Region (SNP) | VAF 4/43 reads (9%) | catalogued as COSV55089834; called by mutect2, varscan2
- MMP17 | c.1317C>A p.H439Q | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV62179027; called by muse, mutect2
- MMS22L | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV51528231; called by muse, mutect2
- MOB2 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57318362; called by muse, mutect2
- MRPS31 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.568); catalogued as COSV60266756; called by muse, mutect2, varscan2
- MUC16 | c.24421G>C p.V8141L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV67461368; called by muse, mutect2, varscan2
- MUC17 | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 41/602 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV60286376; called by muse, mutect2
- MUC17 | c.6686C>T p.T2229I | Missense Mutation (SNP) | VAF 14/456 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV60286392; called by muse, mutect2
- MUC17 | c.7534G>A p.E2512K | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV60286401; called by muse, mutect2
- MUC21 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV66220649; called by muse, mutect2, varscan2
- MUC3A | c.9130C>T p.Q3044* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs1256012743; called by muse, mutect2, varscan2
- MUC4 | c.15991C>T p.H5331Y (on ENST00000463781 / NM_018406.7; = p.H1095Y on NM_004532.6) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as rs765942078, COSV57777484; called by muse, mutect2
- MYF6 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99952811; called by muse, mutect2, varscan2
- MYO1E | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs770130521, COSV55685778; called by mutect2, varscan2
- MYO1F | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV100596593, COSV57792110; called by muse, mutect2
- MYO9A | c.5765A>T p.Y1922F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100613515; called by muse, mutect2
- NAV1 | c.4140A>C p.L1380F | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.081); catalogued as COSV55216761; called by muse, mutect2, varscan2
- NBEAL1 | c.6916C>T p.Q2306* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100074313; called by muse, mutect2
- NBEAL2 | c.6839T>C p.I2280T | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99435916; called by muse, mutect2
- NDST3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV56624993, COSV99630554; called by mutect2, varscan2
- NECTIN1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99872143; called by muse, mutect2, varscan2
- NEUROD6 | c.148A>T p.R50W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV51770654; called by muse, mutect2, varscan2
- NEXN | c.1934T>C p.F645S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53929663; called by muse, mutect2, varscan2
- NIPAL4 | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100357101, COSV61730453; called by muse, mutect2, varscan2
- NLRP5 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.739); catalogued as rs757058002, COSV66763925; called by muse, mutect2
- NOS1 | c.3440A>G p.K1147R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV57610940; called by muse, mutect2, varscan2
- NPHP3 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58129290; called by muse, mutect2, varscan2
- NR1D2 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV56991570; called by muse, mutect2, varscan2
- NUDT17 | c.866G>A p.W289* | Nonsense Mutation (SNP) | VAF 10/153 reads (7%) | catalogued as COSV100566790; called by muse, mutect2
- NUP160 | c.3281A>T p.Y1094F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101021477; called by muse, mutect2
- NUP188 | c.5056G>C p.E1686Q | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65330700; called by muse, mutect2, varscan2
- NUP205 | c.1871G>T p.W624L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53657962, COSV99606642; called by muse, mutect2
- NUP210 | c.1355T>G p.I452S | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54405442; called by muse, mutect2, varscan2
- OBSCN | c.4243G>C p.A1415P | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); catalogued as COSV52765787; called by muse, mutect2
- OBSCN | c.9928G>A p.E3310K | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.122); catalogued as rs1419348435, COSV52744426; called by muse, mutect2
- OBSCN | c.11248G>C p.E3750Q | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); catalogued as COSV52765844; called by muse, mutect2
- OGDHL | c.2665T>C p.F889L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as COSV65101995; called by muse, mutect2
- OR2A1 | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1442715830, COSV101283383; called by muse, mutect2
- OR2AG2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58454995; called by muse, mutect2, varscan2
- OR5J2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV56620910, COSV56621159; called by muse, mutect2, varscan2
- OR8J3 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV56880299; called by muse, mutect2, varscan2
- OTUD4 | c.2845G>A p.A949T (on ENST00000447906 / NM_001366057.1; = p.A884T on NM_001102653.1) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV71381788; called by muse, mutect2
- OTX2 | c.115C>T p.R39C (on ENST00000408990 / NM_172337.3; = p.R47C on NM_021728.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257937; called by muse, mutect2, varscan2
- PACSIN1 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV55058241, COSV55059673; called by muse, mutect2
- PADI4 | c.1395C>G p.D465E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); catalogued as COSV64923834; called by muse, mutect2, varscan2
- PAPLN | c.3800C>T p.S1267L (on ENST00000554301; = p.S1240L on NM_173462.4) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV53716735; called by muse, mutect2, varscan2
- PARD3 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60748602; called by muse, mutect2, varscan2
- PARP1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV64690100; called by muse, mutect2, varscan2
- PCARE | c.2168G>C p.R723T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.32); catalogued as COSV59054468; called by muse, mutect2, varscan2
- PCDHA4 | c.800C>G p.S267* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100793349, COSV100793444; called by muse, mutect2
- PCDHGC4 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV52749687; called by muse, mutect2, varscan2
- PCNX1 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53093137; called by muse, mutect2
- PHF12 | c.2963T>G p.L988R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.332); catalogued as rs778300119, COSV60454044; called by muse, mutect2, varscan2
- PHF13 | c.530C>G p.S177W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV50010919, COSV99275972; called by muse, mutect2, varscan2
- PHIP | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51512056; called by muse, mutect2
- PHTF2 | c.841G>C p.D281H (on ENST00000248550 / NM_001366089.1; = p.D243H on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as COSV99301711; called by muse, mutect2
- PIK3CB | c.2315+1G>A p.X772_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV56685314; called by muse, mutect2, varscan2
- PITPNM2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758735314, COSV54899580; called by muse, mutect2, varscan2
- PKHD1 | c.11600C>G p.S3867C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64387565; called by muse, mutect2
- PLA2G15 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54723063, COSV99547200; called by muse, mutect2
- PLAA | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV101263517; called by muse, mutect2, varscan2
- PLXNC1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51573991; called by muse, mutect2
- PNPLA6 | c.3146C>T p.P1049L (on ENST00000414982 / NM_001166111.2; = p.P1001L on NM_006702.5) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as COSV55377109; called by muse, mutect2
- POLN | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1291851049, COSV101242510; called by muse, mutect2
- PPIL1 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV63836901; called by muse, mutect2
- PPP1R21 | c.853C>G p.P285A | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99682068; called by muse, mutect2
- PPP2R3A | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV53862669; called by muse, mutect2, varscan2
- PRAM1 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV99725566; called by muse, mutect2
- PRDM11 | c.1259C>T p.S420L (on ENST00000530656 / NM_001359633.1; = p.S386L on NM_001256695.1) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV55439394; called by muse, mutect2, varscan2
- PRDM16 | c.1949G>C p.G650A | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV54587705; called by muse, mutect2
- PRG4 | c.3119T>C p.M1040T | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63355297; called by muse, mutect2
- PRKAR1A | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as CD093316, COSV62235482; called by muse, mutect2
- PRKCB | c.174-1G>T p.X58_splice | Splice Site (SNP) | VAF 8/204 reads (4%) | catalogued as COSV57776191; called by muse, mutect2
- PRPF8 | c.4838C>A p.T1613K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100517493; called by muse, mutect2
- PTPN22 | c.1751T>C p.L584S (on ENST00000359785 / NM_001193431.2; = p.L529S on NM_012411.5) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.426); catalogued as COSV63084864; called by muse, mutect2
- PTPRC | c.3457T>G p.S1153A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as COSV100722658, COSV100723332; called by muse, mutect2
- PTPRG | c.1316T>A p.M439K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV55637948; called by muse, mutect2, varscan2
- PTPRT | c.2847+2T>C p.X949_splice | Splice Site (SNP) | VAF 7/99 reads (7%) | catalogued as COSV61975989; called by muse, mutect2
- RAB3C | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV51441458, COSV99277437; called by muse, mutect2
- RAD17 | c.1126G>T p.D376Y (on ENST00000380774 / NM_133339.2; = p.D365Y on NM_002873.1) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV51457416; called by muse, mutect2
- RFX4 | c.482T>G p.V161G (on ENST00000392842 / NM_213594.3; = p.V67G on NM_032491.6) | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as COSV57575169; called by muse, mutect2
- RGS1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV66506711; called by muse, mutect2
- RHAG | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV57703994; called by muse, mutect2, varscan2
- RIMBP2 | c.2205G>A p.P735= | Splice Region (SNP) | VAF 10/57 reads (18%) | catalogued as rs756144691, COSV55470457; called by muse, mutect2, varscan2
- ROR2 | c.2380C>G p.P794A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV65218467; called by muse, mutect2
- RP1L1 | c.6896C>T p.S2299F | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV66754207; called by muse, mutect2, varscan2
- RPS6KA3 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101084388; called by muse, mutect2
- RPS6KC1 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV100873899; called by muse, mutect2
- RRAGA | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV65843261; called by muse, mutect2, varscan2
- RWDD2A | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99392364; called by muse, mutect2
- RWDD2B | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs371354629, COSV54502358; called by muse, mutect2, varscan2
- RYR3 | c.7715T>A p.L2572* (on ENST00000389232; = p.L2573* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV101212771; called by muse, mutect2, varscan2
- S1PR5 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV61013653; called by muse, mutect2
- SALL2 | c.1330G>C p.V444L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV58102955; called by muse, mutect2, varscan2
- SAMD4B | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100080350, COSV58750100, COSV58753067; called by muse, mutect2
- SCAP | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55560719; called by muse, mutect2, varscan2
- SCN1A | c.3350T>A p.I1117N (on ENST00000303395 / NM_001202435.3; = p.I1106N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57667811; called by muse, mutect2
- SCN4A | c.5360G>A p.S1787N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV71126529; called by muse, mutect2, varscan2
- SCN8A | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.991); catalogued as COSV61980093; called by muse, mutect2
- SCNN1A | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57435116; called by muse, mutect2, varscan2
- SCRT1 | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59781088; called by muse, mutect2, varscan2
- SERAC1 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV100894851, COSV65596357; called by muse, mutect2, varscan2
- SERPINB11 | c.287A>C p.Q96P | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV66956833; called by muse, mutect2, varscan2
- SF3B1 | c.3490G>T p.D1164Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV100134726; called by muse, mutect2
- SIN3B | c.1540A>T p.K514* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99931729; called by muse, mutect2, varscan2
- SKA1 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53278646; called by muse, mutect2
- SKAP1 | c.443-2A>T p.X148_splice | Splice Site (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100411808; called by muse, mutect2
- SKP2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs772934208, COSV57041626; called by muse, mutect2
- SLC24A3 | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60117819; called by muse, mutect2, varscan2
- SLC25A44 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV63961714; called by muse, mutect2, varscan2
- SLC30A9 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV52555533; called by muse, mutect2
- SLC38A11 | c.62-1G>A p.X21_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV58052087; called by muse, mutect2, varscan2
- SLC4A1AP | c.1261G>C p.G421R | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58134407, COSV58134549; called by muse, mutect2
- SLC6A12 | c.1152C>G p.F384L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62884846, COSV62885577; called by muse, mutect2, varscan2
- SLC6A2 | c.1810A>T p.R604W | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV54915721; called by muse, mutect2
- SNCAIP | c.2118A>T p.E706D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV54408145; called by muse, mutect2, varscan2
- SOWAHC | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV61780033; called by muse, mutect2, varscan2
- SPECC1L | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs200347225, COSV58657926; called by muse, mutect2, varscan2
- SPRY3 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV57142645, COSV57144266; called by muse, mutect2, varscan2
- SVEP1 | c.8018C>G p.S2673* | Nonsense Mutation (SNP) | VAF 24/127 reads (19%) | catalogued as COSV99929025, COSV99929513; called by muse, mutect2, varscan2
- TAOK2 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV54235086; called by muse, mutect2
- TBX6 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.689); catalogued as rs201241148; called by muse, mutect2, varscan2
- TENT4B | c.1229T>C p.F410S (on ENST00000561678 / NM_001365323.2; = p.F395S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62547189; called by muse, mutect2, varscan2
- TGFBRAP1 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV51511526; called by muse, mutect2
- TLE1 | c.854G>C p.S285T | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100916297; called by muse, mutect2
- TLE4 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 163/176 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104372695, COSV54630809; called by muse, mutect2, varscan2
- TM9SF2 | c.917A>C p.N306T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64506640; called by muse, mutect2
- TMEM131L | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as rs191244971, COSV53643436; called by muse, mutect2, varscan2
- TMEM81 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs748761523, COSV52704171, COSV99196787; called by muse, mutect2, varscan2
- TMEM92 | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV55946234; called by muse, mutect2, varscan2
- TNFRSF10B | c.541A>T p.K181* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as COSV99375399; called by muse, mutect2
- TOLLIP | c.692A>G p.E231G | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55136003; called by muse, mutect2
- TOX4 | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV52968478; called by muse, mutect2
- TP53I3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs368274051; called by muse, mutect2, varscan2
- TPR | c.3188A>C p.Q1063P | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV66600889; called by muse, mutect2
- TRIP12 | c.2435C>G p.S812* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99390264; called by muse, mutect2
- TRPS1 | c.863C>G p.S288C (on ENST00000220888 / NM_001330599.2; = p.S301C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55236740; called by muse, mutect2
- TSPOAP1 | c.2824C>G p.Q942E | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.684); catalogued as COSV99271090; called by muse, mutect2
- TTN | c.36611C>G p.T12204R (on ENST00000591111; = p.T4780R on NM_003319.4) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | PolyPhen benign (0.014); catalogued as COSV100612770, COSV60238507; called by muse, mutect2
- TUBA1A | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.292); catalogued as rs1065730; called by muse, mutect2, varscan2
- UGT1A10 | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV100761966; called by muse, mutect2
- UGT3A1 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs762872593, COSV57097512, COSV99955011; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99511894; called by muse, mutect2
- USPL1 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV54999660; called by muse, mutect2, varscan2
- VPS50 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1421343354, COSV58506991; called by muse, mutect2, varscan2
- VTCN1 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV60223148; called by muse, mutect2, varscan2
- WASHC4 | c.2728G>T p.D910Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59889181, COSV59889311; called by muse, mutect2, varscan2
- WDPCP | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV99705302; called by muse, mutect2
- WDR13 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54331599; called by muse, mutect2, varscan2
- WDR44 | c.411A>T p.L137F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs752974525, COSV54162754; called by muse, mutect2, varscan2
- YWHAG | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56900604; called by muse, mutect2
- ZBED4 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53465238; called by muse, mutect2
- ZBTB5 | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as rs767509727, COSV57039844; called by muse, mutect2, varscan2
- ZDBF2 | c.344A>C p.E115A | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100984892; called by muse, mutect2
- ZMAT3 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1377436362, COSV100265120, COSV60992854; called by muse, mutect2
- ZMYND12 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.193); catalogued as COSV65341911; called by muse, mutect2, varscan2
- ZNF114 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV59944128; called by muse, mutect2, varscan2
- ZNF154 | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV101377538, COSV70744932; called by muse, mutect2
- ZNF257 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV71306934; called by muse, mutect2, varscan2
- ZNF28 | c.1002A>C p.K334N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60422886; called by muse, mutect2
- ZNF284 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs776571445, COSV69690904; called by muse, mutect2, varscan2
- ZNF324B | c.1238T>G p.F413C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100351635; called by muse, mutect2
- ZNF425 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as rs766220882, COSV65201115; called by muse, mutect2, varscan2
- ZNF474 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV56945933; called by muse, mutect2, varscan2
- ZNF518B | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV58722216; called by muse, mutect2, varscan2
- ZNF521 | c.3316G>C p.G1106R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100832175, COSV64122274; called by muse, mutect2
- ZNF599 | c.1512G>C p.E504D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61395978; called by muse, mutect2
- ZNF625 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63241931; called by muse, mutect2, varscan2
- ZNF804B | c.3592G>T p.V1198F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV60824562; called by muse, mutect2
- ZNF808 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV63119519; called by muse, mutect2
- ANAPC1 | c.3176A>T p.D1059V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- AP2B1 | c.2711G>T p.R904L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.243); called by muse, mutect2
- ARV1 | c.163A>T p.I55L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.063); called by muse, mutect2
- CCDC27 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- COPS3 | c.1219-1G>A p.X407_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2
- FCGBP | c.12215C>T p.P4072L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- GCN1 | c.6425C>T p.S2142F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GZF1 | c.1709_1710del p.T570Rfs*29 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | called by pindel, varscan2
- PCYOX1L | c.1085_1086del p.T362Rfs*59 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by pindel, varscan2
- PEA15 | c.347_348del p.S116* | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by pindel, varscan2
- PLA2G1B | c.339_340del p.C113* | Nonsense Mutation (DEL) | VAF 14/124 reads (11%) | called by pindel, varscan2
- PRAMEF20 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2
- TRAV26-2 | c.106C>A p.H36N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TTC3 | c.2490G>C p.K830N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- VANGL2 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.239); called by muse, mutect2
- ZNF710 | c.1949_1950del p.L650Hfs*2 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- ACLY | c.1515G>A p.Q505= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as COSV61250376; called by muse, mutect2, varscan2
- ADAM22 | c.1056G>A p.L352= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55972496; called by muse, mutect2, varscan2
- ADGRB2 | c.2080C>T p.L694= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57072889; called by muse, mutect2, varscan2
- ADGRE2 | c.1872C>T p.L624= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV59691829; called by muse, mutect2, varscan2
- ADK | c.636G>A p.L212= (on ENST00000286621; = p.L195= on NM_001123.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV54204081; called by muse, mutect2
- AKAP8L | c.1092G>A p.K364= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV68473250; called by muse, mutect2
- ANKRD17 | c.5949A>T p.T1983= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as COSV58219050; called by muse, mutect2
- ANKRD49 | c.273G>C p.R91= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57060025; called by muse, varscan2
- AP1B1 | c.165C>G p.V55= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs753900951, COSV58016824; called by muse, mutect2, varscan2
- APOA4 | c.792G>A p.R264= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV63360332; called by muse, mutect2, varscan2
- ARHGEF15 | c.1284C>T p.S428= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs1567676612, COSV62724524; called by muse, mutect2, varscan2
- ARHGEF16 | c.2007G>A p.E669= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV65681818; called by muse, mutect2
- ARHGEF4 | c.900C>A p.I300= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV58121156; called by muse, mutect2
- ARID4A | c.324G>C p.L108= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV62163210; called by muse, mutect2
- ASPM | c.8295G>A p.K2765= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV54123673, COSV54128598; called by muse, mutect2, varscan2
- ASPM | c.6996A>T p.R2332= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV54128607; called by muse, mutect2, varscan2
- ASTN2 | c.906T>C p.P302= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV57771817; called by muse, mutect2
- BNC2 | c.546G>T p.V182= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV66145397; called by muse, mutect2, varscan2
- C3 | c.3372G>A p.V1124= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as COSV55571515; called by muse, mutect2
- CCDC174 | c.945A>G p.E315= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV57980671; called by muse, mutect2
- CD8A | c.522G>A p.T174= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs200085375, COSV52157164; called by muse, mutect2, varscan2
- CEL | c.420C>G p.A140= (on ENST00000673714; = p.A137= on NM_001807.6) | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as COSV60826976; called by muse, mutect2, varscan2
- CELA3A | c.480C>T p.T160= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as rs147682536; called by muse, mutect2, varscan2
- CEP41 | c.357G>T p.S119= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99782682, COSV99782722; called by muse, mutect2
- CLSPN | c.3366T>C p.L1122= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV99230895; called by muse, mutect2
- CNOT8 | c.441C>T p.L147= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs752785048, COSV53585398; called by muse, mutect2, varscan2
- CYP4F11 | c.519C>T p.I173= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99930856; called by muse, mutect2
- DAB1 | c.1470C>T p.D490= (on ENST00000371231; = p.D457= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs368712456; called by mutect2, varscan2
- DCAF1 | c.3009G>T p.T1003= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as rs542435236, COSV100244101; called by muse, mutect2
- DLEC1 | c.1713C>T p.I571= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV57298628; called by muse, mutect2, varscan2
- DOCK8 | c.2085C>T p.P695= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV66619509; called by muse, mutect2, varscan2
- ESPL1 | c.6355C>T p.L2119= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV54475702; called by muse, mutect2, varscan2
- FAM71F2 | c.183C>T p.V61= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1402661115, COSV66352031; called by muse, mutect2, varscan2
- FLVCR1 | c.792G>A p.Q264= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV65323444; called by muse, mutect2
- FRAS1 | c.441C>T p.S147= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99352030; called by muse, mutect2
- GDE1 | c.495A>G p.L165= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV62059362; called by muse, mutect2, varscan2
- GOLGA4 | c.1407A>T p.V469= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV62710386; called by muse, mutect2, varscan2
- GOLGA7B | c.225C>T p.L75= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1331925351, COSV53999989, COSV54000548; called by muse, mutect2, varscan2
- GRIK2 | c.1182G>C p.L394= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV59729986; called by muse, mutect2, varscan2
- GRM2 | c.15T>C p.L5= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99622832; called by muse, mutect2
- HADHB | c.126G>A p.T42= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1475892789, COSV58545899; called by muse, mutect2
- HSP90B1 | c.540A>G p.E180= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100236521; called by muse, mutect2
- IGF2R | c.2155A>C p.R719= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV63628406; called by muse, mutect2, varscan2
- IGLV3-16 | c.228C>T p.I76= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- IKZF2 | c.1413C>T p.F471= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV59577986; called by muse, mutect2, varscan2
- KCNH8 | c.186G>A p.Q62= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV60461833; called by muse, mutect2
- KDM4A | c.555T>C p.F185= | Silent (SNP) | VAF 9/147 reads (6%) | catalogued as COSV64959324; called by muse, mutect2
- KIR2DL3 | c.1011A>C p.P337= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as COSV60896937; called by muse, mutect2
- KLF12 | c.540G>A p.L180= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV66572531; called by muse, mutect2
- LRRC37A3 | c.3963C>T p.V1321= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as COSV58535001, COSV58536547; called by muse, mutect2
- LRRC7 | c.3453G>A p.L1151= (on ENST00000651989 / NM_001370785.2; = p.L1118= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as COSV50443819, COSV50591062; called by muse, mutect2, varscan2
- LSR | c.63C>T p.H21= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV61554959, COSV61556010; called by muse, mutect2
- MBD6 | c.660C>T p.I220= | Silent (SNP) | VAF 15/180 reads (8%) | catalogued as COSV63074066; called by muse, mutect2
- MBLAC2 | c.633T>C p.T211= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV57302063; called by muse, mutect2, varscan2
- MED15 | c.735G>A p.Q245= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV53028741; called by muse, varscan2
- MIB2 | c.3156C>G p.L1052= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV61542502; called by muse, mutect2, varscan2
- MRC1 | c.2079A>G p.K693= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2
- MTR | c.3189T>C p.Y1063= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV63964475; called by muse, mutect2, varscan2
- MYH9 | c.5532G>C p.L1844= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs774510520, COSV53385198; called by muse, mutect2, varscan2
- MYOD1 | c.150G>C p.L50= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- NDST2 | c.2331G>T p.G777= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV55214022; called by muse, mutect2, varscan2
- NIPSNAP1 | c.288C>T p.P96= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53342446; called by muse, mutect2, varscan2
- OR10S1 | c.681C>T p.L227= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV73342751; called by muse, mutect2, varscan2
- PAPPA2 | c.276A>T p.T92= | Silent (SNP) | VAF 17/194 reads (9%) | catalogued as COSV62776838; called by muse, mutect2
- PCDHA1 | c.669A>G p.Q223= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1554117616, COSV100974358; called by muse, mutect2
- PCDHB2 | c.2169G>A p.S723= | Silent (SNP) | VAF 22/221 reads (10%) | catalogued as rs556291584, COSV50586345; called by muse, mutect2, varscan2
- PHACTR2 | c.1683G>A p.L561= | Silent (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- PHACTR4 | c.177A>G p.K59= (on ENST00000373839 / NM_001350159.2; = p.K69= on NM_023923.4) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV65783724; called by muse, mutect2, varscan2
- PIBF1 | c.2142G>C p.V714= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58322435; called by muse, mutect2, varscan2
- PRICKLE4 | c.369G>A p.L123= (on ENST00000359201; = p.L163= on NM_013397.6) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100138888, COSV59254734; called by muse, mutect2, varscan2
- PSMA2 | c.369G>A p.Q123= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV55031206; called by muse, mutect2, varscan2
- QRICH2 | c.69G>A p.K23= | Silent (SNP) | VAF 29/217 reads (13%) | catalogued as rs1333011540, COSV53152673; called by muse, mutect2, varscan2
- RALGDS | c.1113A>T p.A371= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV64426776; called by muse, mutect2, varscan2
- SCN4A | c.4929C>T p.F1643= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs866065846, COSV71126141; called by muse, mutect2
- SDR42E1 | c.1134T>C p.I378= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100200714; called by muse, mutect2
- SERPINA9 | c.1107T>A p.A369= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV54074249; called by muse, mutect2, varscan2
- SF1 | c.1170C>T p.P390= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs142066092; called by muse, mutect2, varscan2
- SHISAL2A | c.390G>C p.V130= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV68979699, COSV68980133; called by muse, mutect2
- SLC35F1 | c.516C>T p.L172= | Silent (SNP) | VAF 23/211 reads (11%) | catalogued as COSV64502078; called by muse, mutect2, varscan2
- SLC6A3 | c.360C>T p.L120= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs148447720; ClinVar: likely benign; called by muse, mutect2
- SMCHD1 | c.1191C>T p.D397= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs535674229, COSV55255686; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SPATA7 | c.261G>A p.E87= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1288865486, COSV50416669; called by muse, mutect2, varscan2
- SPEF2 | c.2124C>T p.I708= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV100607365; called by muse, mutect2
- SPNS2 | c.663C>G p.L221= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100223637; called by muse, mutect2, varscan2
- STYXL1 | c.213G>A p.V71= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV50388429; called by muse, mutect2
- SV2A | c.1344G>C p.L448= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs1553763292, COSV64964579; called by muse, mutect2
- TENM1 | c.1539A>G p.G513= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV64430410; called by muse, mutect2, varscan2
- TGFBRAP1 | c.597G>A p.Q199= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV51511516, COSV99305084; called by muse, mutect2, varscan2
- THBS1 | c.639G>A p.Q213= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV52951456; called by muse, mutect2, varscan2
- TMC3 | c.2565T>A p.L855= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV63922850; called by muse, mutect2, varscan2
- TMEM106C | c.567G>A p.G189= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV56742677; called by muse, mutect2
- TPCN2 | c.786G>A p.L262= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV53728593; called by muse, mutect2
- TTC27 | c.1953T>C p.A651= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV58650861; called by muse, mutect2, varscan2
- VKORC1L1 | c.114G>A p.R38= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100663211; called by muse, mutect2
- VKORC1L1 | c.420C>T p.I140= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs536498943, COSV62488856; called by muse, mutect2, varscan2
- WBP1 | c.693G>T p.V231= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV51968986; called by muse, mutect2, varscan2
- WDR25 | c.543A>G p.L181= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV58935864; called by muse, mutect2, varscan2
- WIPI1 | c.264C>T p.F88= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV50929885; called by muse, mutect2
- XAGE2 | c.108A>G p.E36= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- ZNF142 | c.4752C>T p.L1584= (on ENST00000411696 / NM_001379660.1; = p.L1384= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV68743502; called by muse, mutect2, varscan2
- ZNF256 | c.150A>C p.T50= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV56597112; called by muse, mutect2
- ZNF263 | c.1062G>A p.E354= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV54596170; called by muse, mutect2, varscan2
- ZNF546 | c.579T>C p.V193= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61257741; called by muse, mutect2, varscan2
- ZNF785 | c.867C>T p.C289= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1243807105, COSV67876277; called by muse, mutect2, varscan2
- ZNF99 | c.1692A>C p.P564= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs879026458, COSV101233829; called by muse, mutect2
- ZRANB3 | c.2571C>T p.I857= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99923635; called by muse, mutect2
- COL18A1 | chr21:45455529 C>G | 5'Flank (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100700684; called by muse, mutect2, varscan2
- SNORD116-1 | n.13A>G | RNA (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- SYTL2 | c.1459+2640A>C | Intron (SNP) | VAF 4/52 reads (8%) | catalogued as COSV60358327; called by muse, mutect2
- USH1C | c.1285-7411C>G | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as COSV50015786; called by muse, mutect2, varscan2
